Somatic mutation profile of tumor specimen 0DUVTP from CCDI case PBCLCC, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Ependymoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 1.8 years (658 days).
Specimen 0DUVTP: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b977d22f-5009-410d-bd38-f2b83676d2d3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DUVT0 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/99acccb5-bb57-498a-8715-ce17a811f23e

The open-access MAF lists 5 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, Intron 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL2A1 | c.3026C>T p.A1009V | Missense Mutation (SNP) | VAF 60/378 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.048); catalogued as rs1315629927; called by muse, mutect2, varscan2
- NOS1 | c.3866G>A p.R1289Q | Missense Mutation (SNP) | VAF 192/505 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs199524143, COSV57607574; called by muse, mutect2, varscan2
- RPIA | c.572G>A p.R191H | Missense Mutation (SNP) | VAF 186/601 reads (31%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as rs779800054, COSV52171327; called by muse, mutect2, varscan2
- RRP12 | c.1101C>T p.N367= | Silent (SNP) | VAF 157/400 reads (39%) | catalogued as rs753515335, COSV59668589; called by muse, mutect2, varscan2
- PLEKHG5 | c.-54+183_-54+227del | Intron (DEL) | VAF 12/46 reads (26%) | called by mutect2, varscan2
